Somatic mutation profile of tumor specimen TCGA-EA-A5ZD-01A (aliquot TCGA-EA-A5ZD-01A-11D-A28B-09) from TCGA case TCGA-EA-A5ZD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 40.1 years (14,629 days).
Specimen TCGA-EA-A5ZD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ad039eb-c628-4688-9ad9-7e7a7bdbb641.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A5ZD-10A (Blood Derived Normal), aliquot TCGA-EA-A5ZD-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4024629d-32d1-411f-af0b-32389288eb29

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN3A | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1199412903, COSV51805583, COSV99328527; ClinVar: likely pathogenic; called by muse, mutect2
- CNOT2 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV57506268; called by muse, mutect2, varscan2
- DCAF12L1 | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV64422664; called by muse, mutect2, varscan2
- DZIP1L | c.748A>T p.K250* | Nonsense Mutation (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100551720; called by muse, mutect2
- EPHA3 | c.1217C>G p.T406S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as COSV60703329; called by muse, mutect2, varscan2
- FAT3 | c.6235G>A p.D2079N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53163555, COSV99962904; called by muse, mutect2, varscan2
- GABRB3 | c.1024C>A p.L342I | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV54680600; called by muse, mutect2, varscan2
- MAP3K9 | c.2980C>T p.R994W (on ENST00000554752 / NM_001284230.1; = p.R1008W on NM_033141.4) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs762288591, COSV67122641; called by muse, mutect2, varscan2
- MYO15A | c.9767T>C p.I3256T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs758768524, COSV52764228; called by muse, mutect2, varscan2
- NDST3 | c.2375A>G p.H792R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV56627540; called by muse, mutect2, varscan2
- NOTCH3 | c.1459C>T p.R487* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as rs1284132838, COSV54646925; called by muse, mutect2, varscan2
- RBFOX1 | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV60978031; called by muse, mutect2, varscan2
- SEMA5B | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV52106586; called by muse, mutect2, varscan2
- SKOR1 | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV58249389; called by muse, mutect2, varscan2
- SORCS1 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53862653, COSV99550360; called by muse, mutect2
- SPATA31E1 | c.2868G>C p.R956S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as COSV57794627; called by muse, mutect2, varscan2
- TACC1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs377342873; called by muse, mutect2, varscan2
- USP43 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1353019054, COSV53306304; called by muse, mutect2, varscan2
- PRAMEF15 | c.419G>C p.C140S | Missense Mutation (SNP) | VAF 31/322 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.031); called by muse, varscan2
- HIVEP1 | c.7740G>A p.E2580= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV65104499; called by muse, mutect2, varscan2
- MYBBP1A | c.910C>T p.L304= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs767594039, COSV99626961; called by muse, mutect2, varscan2
- RBM27 | c.3138C>T p.D1046= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs745845587, COSV54593629; called by muse, mutect2, varscan2
- VPS52 | c.18C>T p.T6= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1401757306, COSV71403617; called by muse, mutect2
